TCGA case TCGA-B5-A1MZ — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/838fcc2b-48b4-49dd-b8fc-ff27bbd16b17

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 54.6 years (19,955 days); Year of diagnosis: 2010; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IA; FIGO staging edition year: 2009; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,598 days (4.4 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 32.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 31.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
2. Recurrence of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Vagina, NOS. Age at diagnosis: 56.3 years (20,568 days); Days to diagnosis: 613 days (1.7 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 465 days (1.3 years); Disease response: Tumor Free.
- Day 613 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Vagina, NOS; Days to recurrence: 613 days (1.7 years).
- Days to follow up: 1,598 days (4.4 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 114 kg; Height: 166 cm; BMI: 41.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B5-A1MZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-B5-A1MZ-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
- Sample TCGA-B5-A1MZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B5-A1MZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Indeterminate (neither Pre or Postmenopausal); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form 1: Hypertension diagnosis: No; Pregnancies full term count: 1; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Hypertension diagnosis: No; Pregnancies full term count: 1; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,598 days; disease-specific survival: no event (censored), 1,598 days; disease-free interval: event (new tumor event after initially disease-free), 613 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 613 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-B5-A1MZ-01): tumor purity 0.8, ploidy 2.07, whole-genome doublings 0 (call status: legacy_call).
